Somatic mutation profile of tumor specimen C3N-01649-02 (aliquot CPT0088630009) from CPTAC case C3N-01649, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 52.0 years (18,993 days).
Specimen C3N-01649-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6684e404-eb54-4075-bef9-1b8611d27f89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01649-31 (Blood Derived Normal), aliquot CPT0088680009; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce817981-9654-46e0-8aed-0e517275f102

The open-access MAF lists 123 somatic variants for this specimen: 82 protein-altering or splice-affecting, 26 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 26, Frame Shift Del 8, Intron 7, Nonsense Mutation 5, 3'UTR 3, 5'UTR 3, Frame Shift Ins 3, Splice Site 1, Splice Region 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM5C | c.2080C>T p.R694* | Nonsense Mutation (SNP) | VAF 125/256 reads (49%) | catalogued as rs199422236, CM050330; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.3488del p.G1163Efs*107 | Frame Shift Del (DEL) | VAF 76/435 reads (17%) | catalogued as COSV53899204; called by mutect2, pindel, varscan2
- ADHFE1 | c.906T>A p.D302E | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as rs749339000; called by muse, varscan2
- BAG6 | c.2944C>T p.R982C (on ENST00000676571; = p.R935C on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as rs1299722541; called by muse, mutect2, varscan2
- DNAJC5B | c.198C>G p.N66K | Missense Mutation (SNP) | VAF 125/573 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.348); catalogued as COSV99396043; called by muse, mutect2, varscan2
- FAM227B | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV54818286; called by muse, mutect2, varscan2
- IGF1 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs764732420, COSV61031892; called by muse, mutect2
- KCNK13 | c.1069A>G p.K357E | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1262802385; called by muse, mutect2
- KCNMA1 | c.92C>G p.A31G | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.204); catalogued as rs201551432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCP | c.3011C>T p.P1004L (on ENST00000620378; = p.P1064L on NM_001366122.1) | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1388231266; called by muse, mutect2
- KNDC1 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs750624756, COSV58832969; called by muse, mutect2, varscan2
- LNPEP | c.1349C>A p.S450Y | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs996179795; called by muse, mutect2, varscan2
- NKAIN3 | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 39/414 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as rs1488564267; called by muse, mutect2
- NLRP12 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 77/686 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.276); catalogued as rs769847348, COSV60743393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3R6 | c.1744G>A p.V582M | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs376697464; called by muse, mutect2, varscan2
- PREX1 | c.4484C>T p.A1495V | Missense Mutation (SNP) | VAF 108/498 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs777253458, COSV100906782; called by muse, mutect2, varscan2
- RIMBP2 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs374849427; called by muse, mutect2
- RIPK4 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1415927501; called by muse, mutect2
- SLC6A18 | c.894G>T p.M298I | Missense Mutation (SNP) | VAF 65/294 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs1370463705, COSV57252439; called by muse, mutect2, varscan2
- VHL | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 104/370 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CM004286, CM982006, COSV56553402; called by muse, mutect2, varscan2
- WDR72 | c.1715T>A p.L572* | Nonsense Mutation (SNP) | VAF 109/479 reads (23%) | catalogued as rs1258972337; called by muse, mutect2, varscan2
- ZFYVE21 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52454098; called by muse, mutect2, varscan2
- ADAM19 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2
- ADAMTS20 | c.665A>C p.N222T | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.02); called by muse, varscan2
- C1orf112 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CAND1 | c.3592T>C p.F1198L | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC14 | c.86A>C p.N29T | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CCDC170 | c.329A>C p.E110A | Missense Mutation (SNP) | VAF 118/384 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CCDC7 | c.2605T>C p.S869P | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC87 | c.1361T>A p.L454* | Nonsense Mutation (SNP) | VAF 44/230 reads (19%) | called by muse, mutect2, varscan2
- CELSR3 | c.5365del p.L1789Wfs*14 | Frame Shift Del (DEL) | VAF 42/187 reads (22%) | called by mutect2, pindel, varscan2
- CMPK2 | c.533A>G p.E178G | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTDSP1 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- FAM210B | c.67A>T p.T23S | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRAS1 | c.9056G>A p.S3019N | Missense Mutation (SNP) | VAF 75/344 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- GOLGB1 | c.6850G>T p.G2284W | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- GPX6 | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HELB | c.351T>A p.D117E | Missense Mutation (SNP) | VAF 111/484 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- HELZ | c.4192C>T p.P1398S | Missense Mutation (SNP) | VAF 97/461 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- HERC2 | c.2588A>T p.N863I | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.154); called by muse, mutect2
- HOXC6 | c.137A>G p.Q46R | Missense Mutation (SNP) | VAF 95/432 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HYDIN | c.2428A>G p.N810D | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF22 | c.1810C>T p.L604F | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF7 | c.2476_2479del p.R826Tfs*30 | Frame Shift Del (DEL) | VAF 87/449 reads (19%) | called by mutect2, pindel, varscan2
- LAMA2 | c.6868-1G>A p.X2290_splice | Splice Site (SNP) | VAF 98/292 reads (34%) | called by muse, mutect2, varscan2
- MAMDC2 | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- MARF1 | c.1215dup p.E406Rfs*4 | Frame Shift Ins (INS) | VAF 52/240 reads (22%) | called by mutect2, pindel, varscan2
- MBTPS2 | c.745T>A p.F249I | Missense Mutation (SNP) | VAF 156/332 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MPRIP | c.1385C>G p.T462S | Missense Mutation (SNP) | VAF 63/269 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- MTFR2 | c.63+3A>T | Splice Region (SNP) | VAF 66/220 reads (30%) | called by muse, mutect2, varscan2
- MYO15A | c.7972C>A p.P2658T | Missense Mutation (SNP) | VAF 120/466 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.346); called by muse, varscan2
- MYO18A | c.557G>C p.R186P | Missense Mutation (SNP) | VAF 74/369 reads (20%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCAPH | c.2051A>G p.E684G | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NEFH | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 121/485 reads (25%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- OAS3 | c.360del p.P121Lfs*13 | Frame Shift Del (DEL) | VAF 87/405 reads (21%) | called by mutect2, pindel, varscan2
- OR8K1 | c.499dup p.I167Nfs*2 | Frame Shift Ins (INS) | VAF 74/399 reads (19%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1542_1548del p.S514Rfs*3 | Frame Shift Del (DEL) | VAF 35/115 reads (30%) | called by mutect2, pindel, varscan2
- PIBF1 | c.1253T>C p.V418A | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2
- PMVK | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PRDM4 | c.13A>T p.M5L | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- RASSF4 | c.818_826del p.Y273_K275del | In Frame Del (DEL) | VAF 34/164 reads (21%) | called by mutect2*, pindel, varscan2
- RBBP4 | c.833G>A p.C278Y | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- RIBC1 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- RMI1 | c.528del p.G178Vfs*5 | Frame Shift Del (DEL) | VAF 53/238 reads (22%) | called by mutect2, pindel, varscan2
- SCN2A | c.3527_3531del p.V1176Efs*26 | Frame Shift Del (DEL) | VAF 93/481 reads (19%) | called by mutect2, pindel, varscan2
- SEL1L | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SERINC1 | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SH3RF3 | c.224A>G p.H75R | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIGLEC8 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- SLC27A6 | c.1217T>A p.M406K | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- STAB2 | c.2005_2006del p.K669Efs*22 | Frame Shift Del (DEL) | VAF 38/220 reads (17%) | called by mutect2, pindel, varscan2
- STK32A | c.112T>A p.C38S | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STXBP1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 39/532 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2
- TBC1D14 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 89/386 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TNKS | c.1302G>A p.W434* | Nonsense Mutation (SNP) | VAF 61/247 reads (25%) | called by muse, mutect2, varscan2
- TRPM8 | c.1518C>G p.Y506* | Nonsense Mutation (SNP) | VAF 81/602 reads (13%) | called by muse, mutect2, varscan2
- TTC23 | c.1261T>G p.S421A | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBE2M | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP17L1 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 80/364 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- VIRMA | c.1201G>C p.V401L | Missense Mutation (SNP) | VAF 91/365 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- WDR11 | c.3143G>C p.S1048T | Missense Mutation (SNP) | VAF 40/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- XBP1 | c.30_31insTCGGCCG p.A11Sfs*8 | Frame Shift Ins (INS) | VAF 38/180 reads (21%) | called by mutect2, pindel, varscan2
- AGRN | c.4908C>T p.F1636= | Silent (SNP) | VAF 20/312 reads (6%) | catalogued as rs773269271, COSV101038831; called by muse, mutect2
- CASS4 | c.2289G>T p.A763= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as rs772143299, COSV64386784, COSV64387957; called by muse, mutect2, varscan2
- CNOT4 | c.1785C>T p.T595= (on ENST00000541284 / NM_001190850.1; = p.T592= on NM_001190849.2) | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as rs749528170; called by muse, mutect2, varscan2
- DENND2B | c.1696C>T p.L566= | Silent (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- EGFR | c.639C>T p.I213= | Silent (SNP) | VAF 87/530 reads (16%) | catalogued as COSV51844520, COSV99287865; called by muse, varscan2
- HP1BP3 | c.1479C>T p.P493= | Silent (SNP) | VAF 89/451 reads (20%) | called by muse, mutect2, varscan2
- IGHA1 | c.132C>T p.S44= | Silent (SNP) | VAF 16/470 reads (3%) | catalogued as rs758966949; called by muse, mutect2
- KCNIP4 | c.615C>G p.P205= | Silent (SNP) | VAF 86/439 reads (20%) | called by muse, mutect2, varscan2
- KIF7 | c.3258C>T p.A1086= | Silent (SNP) | VAF 84/528 reads (16%) | called by muse, mutect2, varscan2
- LACRT | c.150A>T p.P50= | Silent (SNP) | VAF 44/218 reads (20%) | called by muse, mutect2, varscan2
- LRRTM3 | c.729C>G p.V243= | Silent (SNP) | VAF 87/434 reads (20%) | called by muse, mutect2, varscan2
- MDH1B | c.393C>T p.P131= | Silent (SNP) | VAF 60/252 reads (24%) | catalogued as rs560888236, COSV100982342; called by muse, mutect2, varscan2
- NCAPD3 | c.2877C>T p.N959= | Silent (SNP) | VAF 88/382 reads (23%) | catalogued as rs763564712; called by muse, mutect2, varscan2
- NOTCH3 | c.1245C>T p.F415= | Silent (SNP) | VAF 46/540 reads (9%) | called by muse, mutect2
- OR8D4 | c.567C>T p.C189= | Silent (SNP) | VAF 40/298 reads (13%) | catalogued as rs954420125; called by muse, mutect2, varscan2
- OTUD6A | c.261G>A p.R87= | Silent (SNP) | VAF 36/227 reads (16%) | catalogued as rs1348882403; called by muse, mutect2, varscan2
- PCLO | c.15036G>A p.K5012= | Silent (SNP) | VAF 15/268 reads (6%) | catalogued as rs1364977542; called by muse, mutect2
- PLXNB2 | c.1512C>T p.A504= | Silent (SNP) | VAF 43/161 reads (27%) | catalogued as rs758353384; called by muse, mutect2, varscan2
- SAMD9L | c.1830C>T p.S610= | Silent (SNP) | VAF 60/393 reads (15%) | called by muse, mutect2, varscan2
- STARD6 | c.219A>G p.T73= | Silent (SNP) | VAF 42/206 reads (20%) | called by muse, mutect2, varscan2
- TASOR2 | c.2724A>G p.E908= | Silent (SNP) | VAF 49/457 reads (11%) | called by muse, mutect2, varscan2
- TEC | c.1149G>T p.V383= | Silent (SNP) | VAF 67/317 reads (21%) | called by muse, mutect2, varscan2
- TGM7 | c.1188G>T p.V396= | Silent (SNP) | VAF 34/417 reads (8%) | called by muse, mutect2
- TRAPPC13 | c.798C>G p.G266= | Silent (SNP) | VAF 38/239 reads (16%) | catalogued as COSV51560533; called by muse, mutect2, varscan2
- USP12 | c.1044C>T p.Y348= | Silent (SNP) | VAF 19/352 reads (5%) | catalogued as rs369692707; called by muse, mutect2
- VWA3B | c.810C>T p.F270= | Silent (SNP) | VAF 42/250 reads (17%) | called by muse, mutect2, varscan2
- AC126283.2 | c.-15_-7del | 5'UTR (DEL) | VAF 45/340 reads (13%) | called by mutect2, pindel, varscan2
- CCDC74B | c.295+69C>T | Intron (SNP) | VAF 19/56 reads (34%) | catalogued as rs370679590; called by muse, mutect2, varscan2
- CHIT1 | c.*363A>C | 3'UTR (SNP) | VAF 117/466 reads (25%) | called by muse, mutect2, varscan2
- CST9LP1 | n.433G>A | RNA (SNP) | VAF 17/156 reads (11%) | catalogued as rs756413981; called by muse, mutect2, varscan2
- FLVCR2 | c.670-16492G>A | Intron (SNP) | VAF 49/239 reads (21%) | called by muse, mutect2, varscan2
- FLVCR2 | c.670-16491C>A | Intron (SNP) | VAF 50/241 reads (21%) | called by muse, mutect2, varscan2
- FLYWCH1 | c.1514-477G>A | Intron (SNP) | VAF 89/322 reads (28%) | called by muse, mutect2, varscan2
- MLIP | c.1113+12908C>A | Intron (SNP) | VAF 24/195 reads (12%) | called by muse, varscan2
- PRKCG | c.*130C>A | 3'UTR (SNP) | VAF 32/108 reads (30%) | called by muse, mutect2, varscan2
- SAMD4B | c.*195C>T | 3'UTR (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- TP53AIP1 | chr11:128935044 del A | 3'Flank (DEL) | VAF 54/307 reads (18%) | called by mutect2, pindel*
- TRAV10 | c.-9A>C | 5'UTR (SNP) | VAF 53/238 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.10361-4950_10361-4948del | Intron (DEL) | VAF 139/703 reads (20%) | called by mutect2, pindel, varscan2
- TTN | c.10360+2263A>G | Intron (SNP) | VAF 60/562 reads (11%) | called by muse, mutect2, varscan2
- XRCC5 | c.-60G>C | 5'UTR (SNP) | VAF 72/337 reads (21%) | called by muse, mutect2, varscan2
